Gene-level copy-number profile of tumor specimen TCGA-22-0944-01A from TCGA case TCGA-22-0944, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.1 years (22,329 days).
Specimen TCGA-22-0944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.04b2bf95-b39a-452e-a4f8-006ec2802bd5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-0944-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac5ad4e4-6707-46c9-937c-b5d8bbaf3b2f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 13; copy number 2: 14,122; copy number 3: 7,704; copy number 4: 30,869; copy number 5: 3,205; copy number 6: 2,124; copy number 7: 677; copy number 8: 574; copy number 9: 434; copy number 56: 12; copy number 68: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-0944-01A-01D-0685-01): tumor purity 0.66, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,556,069–11,771,350, 3 genes (within-gene range 0–2): VGLL4, AC022001.2, AC022001.3.
- chr21:15,928,296–20,828,622, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 456 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,828,736–174,378,005, 10 genes, copy number 9: ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:179,971,494–198,222,513, 424 genes, copy number 9 (broad region; genes not listed).
- chr17:39,401,793–39,927,601, 22 genes, copy number 56–68: AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
